Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6365, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6365-01A (Primary Tumor).

[page 1 of 3]
SPECIMENS:

- A. POSTERIOR BLADDER NECK
- B. RIGHT PELVIC LYMPH NODES
- C. LEFT PELVIC LYMPH NODES
- D. PROSTATE

TCGA - G9 - 6365

SPECIMEN(S):

- A. POSTERIOR BLADDER NECK
- B. RIGHT PELVIC LYMPH NODES
- C. LEFT PELVIC LYMPH NODES
- D. PROSTATE

MRI of A Bone and Fine

GROSS DESCRIPTION:

A. POSTERIOR BLADDER NECK

Received in formalin labeled with the patient's identification and designated "posterior bladder neck" is a fragment of unoriented tan firm tissue measuring 1.1 x 0.9 x 0.3 cm. Entirely submitted, A1.

B. RIGHT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and designated "right pelvic lymph nodes" are multiple fragments of adipose tissue measuring 5.5 x 2.2 x 1 cm in aggregate. Two possible lymph nodes are identified measuring 1.6 x 1.4 x 0.2 cm and 3.5 x 2 x 0.9 cm. Cassettes are submitted as follows:

B1: One lymph node

B2-B4: One sectioned lymph node

B5: Additional possible lymph nodes

C. LEFT PELVIC LYMPH NODES

Received in formalin labeled with the patient's identification and designated "left pelvic lymph nodes" are multiple fragments of adipose tissue measuring 6.4 x 5.5 x 1.5 cm in aggregate. Multiple possible lymph nodes are identified ranging from 0.5 x 0.5 x 0.2 up to 5 x 1.4 x 0.8 cm. Cassettes are submitted as follows:

C1: Two possible lymph nodes

C2: One possible lymph node

C3: One possible lymph node

C4-C5: One sectioned lymph node

D. PROSTATE

Received fresh labeled with the patient's identification and designated "prostate" is a resected prostate gland weighing 91 g and measuring 7.5-cm from right to left, 5-cm from anterior to posterior, and 4.5-cm from apex to base. The capsule has a shaggy rough appearance. Ink code: Apex-red, anterior-orange, posterior-black, base-blue, right-green, left - yellow. The apex and base are removed from the specimen to yield a new weight of 52 g. The specimen is serially sectioned from apex to base revealing firm tan bulging nodular parenchyma. The right and left remnants of seminal vesicle, 2 x 1.8 x 0.2 cm and 1.5 x 1.2 x 0.3 cm, respectively, are bisected to show beige tan cystic tissue. The right and left vas deferens, 3 x 0.3 cm and 3.2 x 0.5 cm, respectively, are sectioned to show firm tan tube structure. A portion of the specimen is submitted which procurement, the remainder is entirely submitted:

D1-D3: Right apex

D4-D6: Left Apex

D7: Level 1 right anterior

D8: Level 1 right posterior

D9: Level 1 left anterior

D10: Level 1 left posterior

D11-D13: Level 2 capsule, right side

D14-D16: Level 2 capsule, left side

D17-D18: Right lateral base

D19-D24: Right base

D25: Right base with proximal urethral margin

D26-D27: Left base with proximal urethral margin

D28-D32: Left base, with left seminal vesicle remnant

D33-D34: Left lateral base

D35: Right seminal vesicle, right vas, representative sections

D36: Representative sections left vas

[page 2 of 3]
DIAGNOSIS:

A. POSTERIOR BLADDER NECK, EXCISION:

- NEGATIVE FOR TUMOR

B. RIGHT PELVIC LYMPH NODES, EXCISION:

- EIGHT (8) LYMPH NODES, NEGATIVE FOR TUMOR

C. LEFT PELVIC LYMPH NODES, EXCISION:

- FIVE (5) LYMPH NODES, NEGATIVE FOR TUMOR

D. PROSTATE, SEMINAL VESICLES, AND VASA DEFERENTIA (RADICAL PROSTATECTOMY):

- PROSTATIC ADENOCARCINOMA, GLEASON SCORE 3 + 4 = 7 INVOLVING RIGHT AND LEFT LOBES OF PROSTATE (APPROXIMATELY 20% OF PROSTATE TISSUE)

- TUMOR INVOLVES MUSCULAR WALL OF LEFT SEMINAL VESICLE

- TUMOR INVOLVES INKED LEFT BASE WITH PROXIMAL URETHRAL MARGIN (MULTIFOCAL)

- LINEAR DISTANCE OF POSITIVE MARGIN: 1.1-MM (1080 MICROMETER), <1-MM (422.81 MICROMETER) AND <1-MM (87 MICROMETER)

- PERINEURAL INVASION IDENTIFIED

- NO DEFINITIVE ANGIOLYMPHATIC INVASION IDENTIFIED

- RIGHT SEMINAL VESICLE, RIGHT AND LEFT VAS DEFERENS, NEGATIVE FOR TUMOR

- SEE NOTE

NOTE: THE DIAGNOSIS OF PROSTATIC ADENOCARCINOMA INVOLVING SEMINAL VESICLE IS SUPPORTED BY THE FAILURE OF IMMUNOPEROXIDASE STAINING FOR HIGH MOLECULAR WEIGHT CYTOKERATIN AND P63 TO DEMONSTRATE BASAL CELLS IN THE ATYPICAL GLANDS. ALSO FAVORING THE DIAGNOSIS OF PROSTATIC CANCER IS THAT STAINS FOR PSA AND PSAP (MARKERS PREFERENTIALLY EXPRESSED IN PROSTATE CANCER) ARE POSITIVE (TISSUE BLOCK D28). P504S IMMUNOPEROXIDASE STAIN IS NONCONTRIBUTORY.

NOTE: THE DIAGNOSIS OF PROSTATIC ADENOCARCINOMA INVOLVING LEFT BASE WITH PROXIMAL URETHRAL MARGIN IS SUPPORTED BY THE FAILURE OF IMMUNOPEROXIDASE STAINING FOR HIGH MOLECULAR WEIGHT CYTOKERATIN AND P63 TO DEMONSTRATE BASAL CELLS IN THE ATYPICAL GLANDS AT THE INKED SURFACE (TISSUE BLOCK D26). P504S IMMUNOPEROXIDASE STAIN IS NONCONTRIBUTORY.

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: POSTERIOR BLADDER NECK

B: RIGHT PELVIC LYMPH NODES

C: LEFT PELVIC LYMPH NODES

D: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 20%

Gleason Grade/Sum:: Grade 3 + 4 , Sum 7

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: Yes

[page 3 of 3]
Left
Muscular Wall Invasion: Yes
Lumen Invasion: No
Periprostatic Fat Involved: No
Bladder Neck Involved: Yes
Margins Involvement: Yes
Location: Left base with proximal urethral margin
Linear Distance: Diffuse (>10mm or Multifocal)
Frozen Performed: No
Lymph Nodes: Negative Right 0 / 8 Left 0 / 5
Other Pathologic Findings: BPH
Pathological Staging (pTNM): T 4 N 0 M x

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate carcinoma

Source: NCI Genomic Data Commons file eda91d5a-e4c3-484d-ac6b-1d09f14156ea (TCGA-G9-6365.0F1F5E1B-4086-4A77-96BA-2108ABDDE80F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).